Somatic mutation profile of tumor specimen MMRF_2838_1_BM_CD138pos (aliquot MMRF_2838_1_BM_CD138pos_T1_KHS5U_L16572) from MMRF case MMRF_2838, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.5 years (23,177 days).
Specimen MMRF_2838_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e2d0b28-8d5a-426d-81a6-9ffacf413e4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2838_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2838_1_PB_WBC_C2_KHS5U_L16670; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2e59c83-95df-4558-999a-62687bbd4051

The open-access MAF lists 104 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 28, Silent 12, Intron 9, 5'UTR 5, 3'Flank 4, Splice Site 2, Nonsense Mutation 2, 5'Flank 2, Frame Shift Del 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 24/208 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AJAP1 | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65452326; called by muse, mutect2, varscan2
- CD1B | c.981-1G>T p.X327_splice | Splice Site (SNP) | VAF 22/388 reads (6%) | catalogued as COSV100939264; called by muse, mutect2
- CFTR | c.577del p.E193Kfs*22 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | catalogued as CM941970, CM950240, COSV50044195; called by mutect2, pindel, varscan2
- DCDC1 | c.5191G>T p.V1731L (on ENST00000597505 / NM_001367979.1; = p.V838L on NM_020869.3) | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV58005414; called by mutect2, varscan2
- DNAJC24 | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.943); catalogued as rs766307254; called by muse, mutect2, varscan2
- DPYD | c.1172T>C p.L391P | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs1325769046; called by muse, mutect2, varscan2
- FHDC1 | c.3102C>A p.S1034R | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99471586; called by muse, mutect2, varscan2
- FOXD2 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256360797, COSV58304434; called by muse, mutect2, varscan2
- H3C2 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 119/262 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV52519212; called by muse, varscan2
- HAS1 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1176908583, COSV55787404; called by muse, mutect2, varscan2
- IGHV2-70 | c.308T>A p.M103K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs534782395; called by muse, varscan2
- INPP4A | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs555007396, COSV50818394; called by muse, mutect2, varscan2
- KCNJ12 | c.1145C>A p.A382D | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs1267929234; called by muse, mutect2
- PCDHB8 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV50766358, COSV50810023, COSV99177350; called by muse, mutect2, varscan2
- PTPRR | c.1480C>T p.L494F | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51738847; called by muse, mutect2, varscan2
- RAB14 | c.470+1G>A p.X157_splice | Splice Site (SNP) | VAF 11/24 reads (46%) | catalogued as COSV65788389; called by muse, mutect2
- TLE4 | c.1459G>T p.G487W | Missense Mutation (SNP) | VAF 6/171 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54625555; called by muse, mutect2
- AMY1C | c.990C>A p.F330L | Missense Mutation (SNP) | VAF 28/628 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- BIRC6 | c.13076T>A p.V4359E | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- C14orf39 | c.1684G>T p.G562C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- CACNA1E | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DOCK1 | c.4444G>A p.V1482I | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- EYS | c.8853C>G p.D2951E (on ENST00000370621 / NM_001292009.1; = p.D2930E on NM_001142800.2) | Missense Mutation (SNP) | VAF 120/252 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- IGHJ1 | c.17_18insGTGGGGC p.H6Qfs*? | Frame Shift Ins (INS) | VAF 14/20 reads (70%) | called by pindel, varscan2
- KCTD20 | c.419A>T p.D140V | Missense Mutation (SNP) | VAF 58/351 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KREMEN2 | c.725A>C p.D242A | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, varscan2
- LCE2C | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.624); called by muse, varscan2
- MYBPH | c.700C>G p.R234G | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO15A | c.6974G>C p.W2325S | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- MYO9A | c.757A>T p.I253F | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCDHGB4 | c.2041G>T p.D681Y | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- PLD3 | c.161T>A p.M54K | Missense Mutation (SNP) | VAF 100/199 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PYROXD2 | c.1461_1463del p.I487_E488delinsM | In Frame Del (DEL) | VAF 24/96 reads (25%) | called by mutect2, pindel, varscan2
- RAD50 | c.2696A>T p.Q899L | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- SIRPD | c.73+5G>T | Splice Region (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- SLF1 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- TLE4 | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 6/171 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2
- TMTC2 | c.1596T>A p.N532K | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- TRIM55 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 29/55 reads (53%) | called by muse, mutect2, varscan2
- TRIP12 | c.4694T>A p.L1565* | Nonsense Mutation (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- TTC39B | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.55); called by muse, varscan2
- XDH | c.1481T>C p.L494P | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADAMTS19 | c.3189T>A p.R1063= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV99177130; called by muse, mutect2, varscan2
- ALDH16A1 | c.2356C>T p.L786= | Silent (SNP) | VAF 38/68 reads (56%) | catalogued as COSV52618507; called by muse, mutect2, varscan2
- BHLHE41 | c.534G>A p.Q178= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as rs758835455, COSV54379771; called by muse, mutect2, varscan2
- DISP1 | c.3972C>A p.G1324= | Silent (SNP) | VAF 32/159 reads (20%) | called by muse, mutect2, varscan2
- ERCC4 | c.51G>A p.E17= | Silent (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- FJX1 | c.1017T>C p.N339= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as rs1565388990; called by muse, mutect2, varscan2
- KCNB1 | c.1227C>A p.I409= | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- SEC14L3 | c.321T>C p.D107= | Silent (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- SLC52A3 | c.891G>A p.P297= | Silent (SNP) | VAF 45/99 reads (45%) | catalogued as rs373350870; called by muse, mutect2, varscan2
- TAMALIN | c.405C>T p.V135= | Silent (SNP) | VAF 39/212 reads (18%) | called by muse, mutect2, varscan2
- TBC1D9B | c.3336C>T p.G1112= (on ENST00000356834 / NM_198868.3; = p.G1095= on NM_015043.4) | Silent (SNP) | VAF 65/152 reads (43%) | catalogued as rs528086730, COSV52972212; called by muse, mutect2, varscan2
- ZNF474 | c.210A>G p.K70= | Silent (SNP) | VAF 57/144 reads (40%) | called by muse, mutect2, varscan2
- AC006486.1 | c.23-3156del | Intron (DEL) | VAF 19/34 reads (56%) | called by mutect2, pindel, varscan2
- ADGRL4 | c.*782A>T | 3'UTR (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- AL157893.1 | chr10:87213780 C>T | 3'Flank (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- ANHX | c.-48G>A | 5'UTR (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.*1920A>T | 3'UTR (SNP) | VAF 15/39 reads (38%) | called by mutect2, varscan2
- B3GALT5 | c.-523-7270A>G | Intron (SNP) | VAF 76/178 reads (43%) | called by muse, mutect2, varscan2
- C2CD5 | c.*312T>C | 3'UTR (SNP) | VAF 26/29 reads (90%) | catalogued as rs1256612399; called by muse, mutect2, varscan2
- CLLU1 | n.1785T>G | RNA (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- DRD5 | c.*203G>A | 3'UTR (SNP) | VAF 99/233 reads (42%) | called by muse, mutect2, varscan2
- EN2 | c.-40G>A | 5'UTR (SNP) | VAF 42/79 reads (53%) | called by muse, mutect2, varscan2
- FABP2 | c.*901A>C | 3'UTR (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- FAM189A1 | c.*297C>A | 3'UTR (SNP) | VAF 39/81 reads (48%) | called by muse, mutect2, varscan2
- FCER1G | c.*204A>C | 3'UTR (SNP) | VAF 61/146 reads (42%) | called by muse, mutect2, varscan2
- FGFR3 | c.*229_*261del | 3'UTR (DEL) | VAF 10/102 reads (10%) | called by mutect2, pindel
- GDE1 | c.*1048C>T | 3'UTR (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- GNPDA2 | c.769+2002A>T | Intron (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- GREM2 | c.*3203del | 3'UTR (DEL) | VAF 31/73 reads (42%) | catalogued as rs755705823; called by mutect2, pindel, varscan2
- HAUS1 | c.*172A>C | 3'UTR (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- HMGN4 | c.*1268C>T | 3'UTR (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- ISL1 | c.219-1166C>T | Intron (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- KRTAP17-1 | c.*151C>T | 3'UTR (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- LGALS2 | c.-64C>T | 5'UTR (SNP) | VAF 23/84 reads (27%) | catalogued as rs914882953; called by muse, mutect2, varscan2
- LINC00470 | n.1726-67A>G | Intron (SNP) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- LRRC14 | c.*2311T>C | 3'UTR (SNP) | VAF 137/272 reads (50%) | called by muse, mutect2, varscan2
- MACROD2 | chr20:13995369 G>A | 5'Flank (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- MAGIX | chrX:49167395 G>A | 3'Flank (SNP) | VAF 6/88 reads (7%) | catalogued as COSV66242610; called by muse, mutect2
- MMP20 | c.*74C>A | 3'UTR (SNP) | VAF 52/77 reads (68%) | called by muse, mutect2, varscan2
- MRPL28 | c.288+124C>T | Intron (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2, varscan2
- MTRF1L | c.*1395T>G | 3'UTR (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- NCL | chr2:231464535 G>A | 5'Flank (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- OLFM3 | c.*350A>T | 3'UTR (SNP) | VAF 13/46 reads (28%) | catalogued as rs560217644, COSV58803013; called by muse, mutect2, varscan2
- OPRK1 | c.*2992T>A | 3'UTR (SNP) | VAF 36/83 reads (43%) | called by muse, mutect2, varscan2
- OSBPL6 | c.*3655_*3661del | 3'UTR (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- PCGF5 | c.*3383C>G | 3'UTR (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- PIGA | c.*613C>A | 3'UTR (SNP) | VAF 30/31 reads (97%) | called by muse, mutect2, varscan2
- PTPRB | chr12:70520940 T>A | 3'Flank (SNP) | VAF 17/87 reads (20%) | called by muse, mutect2, varscan2
- SCRT2 | c.*571T>C | 3'UTR (SNP) | VAF 54/108 reads (50%) | called by muse, mutect2, varscan2
- SDC1 | c.*1020G>C | 3'UTR (SNP) | VAF 32/164 reads (20%) | called by muse, mutect2, varscan2
- SH3RF1 | c.*1743_*1774delinsACAATGTATATTATGTTCCTGTGTGTTGAATTTA | 3'UTR (INS) | VAF 4/39 reads (10%) | called by pindel, varscan2*
- SLC38A11 | c.-224C>G | 5'UTR (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- STAU2 | c.1530+24216C>T | Intron (SNP) | VAF 32/182 reads (18%) | called by muse, mutect2, varscan2
- SVEP1 | c.*336C>T | 3'UTR (SNP) | VAF 15/40 reads (38%) | catalogued as rs751537182; called by muse, mutect2, varscan2
- SYNPO | chr5:150657434 A>T | 3'Flank (SNP) | VAF 10/47 reads (21%) | catalogued as rs62380600; called by muse, varscan2
- TBC1D8B | c.-180G>T | 5'UTR (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- TMCO5A | c.*131T>A | 3'UTR (SNP) | VAF 33/203 reads (16%) | called by muse, mutect2, varscan2
- TMCO5A | c.*394T>A | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- TMEM143 | c.24-13T>G | Intron (SNP) | VAF 25/108 reads (23%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3093+82C>A | Intron (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- ZNF37A | c.*746A>T | 3'UTR (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
